Surgical pathology report (de-identified scan), TCGA case TCGA-S2-AA1A, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Albert Einstein Medical Center, specimen TCGA-S2-AA1A-01A (Primary Tumor).

[page 1 of 4]
MRN: [REDACTED]
Patient: [REDACTED]
Admission Date: [REDACTED]
Ordering Physician: [REDACTED]

Sex/DOB: [REDACTED]
Discharge Date: [REDACTED]

Female [REDACTED]

Surgical Pathology Report

Collected Date/Time:
Received Date/Time:

Accession Number: [REDACTED]

Final Diagnosis

- A. LYMPH NODES, LEVEL VII, LYMPHADENECTOMY:
- NO TUMOR SEEN IN 3 LYMPH NODES.
- B. LYMPH NODES, HILAR, LYMPHADENECTOMY:
- NO TUMOR SEEN IN ONE LYMPH NODE.
- C. LYMPH NODES, LEVEL II, LYMPHADENECTOMY:
- NO TUMOR SEEN IN 6 LYMPH NODES.
- D. LYMPH NODES, LEVEL IV, LYMPHADENECTOMY:
- NO TUMOR SEEN IN 2 LYMPH NODES.
- E. LUNG, RIGHT UPPER LOBE, LOBECTOMY:
- INVASIVE MUCINOUS ADENOCARCINOMA.
- NO TUMOR SEEN IN 2 LYMPH NODES.
- SEE SYNOPTIC REPORT AND NOTE.

ICD O-3
Carcinoma, bronchioloalveolar, mucinous
825813
Site: R Lung, upper lobe c34.1
JW 2/24/14

NOTE: there are multiple foci of invasion with desmoplastic response in a background of a "lepidic" involvement of alveolar spaces, the largest focus measures 5.2 millimeters.

(Electronic signature)
Verified:

Synoptic Report

SPECIMEN:

Lobe(s) of lung: right upper

PROCEDURE:

Lobectomy

Printed by:
Copied to:
Distribute to:

Page 1 of 4

Print Date/Time:

Patient Locations:

[page 2 of 4]
MRN: [REDACTED]
Patient: [REDACTED]

Sex/DOB: Female [REDACTED]

Surgical Pathology Report

Collected Date/Time:
Received Date/Time:

Accession Number: [REDACTED]

SPECIMEN INTEGRITY:

Intact

SPECIMEN LATERALITY:

Right

TUMOR SITE:

Upper lobe

TUMOR SIZE:

Greatest dimension: 2.5 cm

Additional dimensions: 1.5 x 1.0 cm

TUMOR FOCALITY:

Unifocal

HISTOLOGIC TYPE:

Invasive mucinous (former mucinous bronchoalveolar carcinoma)

HISTOLOGIC GRADE:

G1: Well differentiated

VISCERAL PLEURA INVASION:

Not identified

TUMOR EXTENSION:

Not applicable

BRONCHIAL MARGIN:

Uninvolved by invasive carcinoma

VASCULAR MARGIN:

Uninvolved by invasive carcinoma

PARENCHYMAL MARGIN:

Uninvolved by invasive carcinoma

PARIETAL PLEURAL MARGIN:

Not applicable

CHEST WALL MARGIN:

Not applicable

OTHER ATTACHED TISSUE MARGIN:

Not applicable

TREATMENT EFFECT:

Not applicable

LYMPH-VASCULAR INVASION:

Not identified

PRIMARY TUMOR (pT):

pT1b: Tumor greater than 2 cm, but 3 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus)

REGIONAL LYMPH NODES (pN):

pN0: No regional lymph node metastasis

Number examined: 14

Number involved: 0

DISTANT METASTASIS (pM):

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:

[page 3 of 4]
MRN: [REDACTED]

Patient: [REDACTED]

Sex/DOB: Female [REDACTED]

Surgical Pathology Report

Collected Date/Time:

Accession Number: [REDACTED]

Received Date/Time:

Atypical adenomatous hyperplasia

Source of Specimen

- A Lymph Nodes, Level 7
- B Lymph Nodes, Hilar
- C Lymph Nodes, Level 2
- D Lymph Nodes, Level 4
- E Right Upper Lobe

Clinical Information

PRE-OP DIAGNOSIS: Lung cancer

POST-OP DIAGNOSIS: Same

TYPE OF PROCEDURE: right VATS, lymphadenectomy

Gross Description

Specimen is received in 5 parts:

A. The specimen is labeled "LEVEL VII" and is received in formalin. It consists of 3 black tan lymph nodes ranging from 0.6 x 0.5 x 0.3-0.8 x 0.7 x 0.4 cm. Entirely submitted in cassette A1.

B. The specimen is labeled "HILAR LYMPH NODE" and is received in formalin. It consists of a single black tan lymph node measuring 1.2 x 0.5 x 0.3 cm. Entirely submitted in cassette B1.

C. The specimen is labeled "LEVEL II" and is received in formalin. It consists of 6 black tan lymph nodes ranging from 0.5 x 0.5 x 0.3-1.5 x 0.7 x 0.5 cm. Entirely submitted as follows

C1 = 5 lymph nodes

C2 = largest lymph node, bisected

D. The specimen is labeled "LEVEL IV" and is received in formalin. It consists of 2 lymph nodes measuring 0.5 x 0.5 x 0.3-1.0 x 0.5 x 0.3 cm. Entirely submitted in cassette D1.

E. The specimen is labeled "RIGHT UPPER LOBE" and is received in formalin. It consists of a lobe of the lung measuring 15 x 12 x 6 cm and weighing 270 g. The pleural surface is pink-purple and smooth. The soft tissue margin and bronchial margin of resection are stapled shut. On section the cut surface shows 2.5 x 1.5 x 1 cm an ill-defined gray-tan mass is noted which is 6 cm away from the bronchial margin of resection. This mass is located in subpleurally. The pleura overlying this mass is inked black and covered with smooth surface without any papillary excrescences. A remaining portion of the lung shows dark red congested parenchyma without other lesions. At the hilum lymph node is not identified. Representative sections are submitted as follows:

E1 = mass for further study

E2 = bronchial margin and blood vessel margin of resection

E3 = soft tissue margin of resection

E4-E5 = remaining entire mass

E6 = random section of lung

Specimen is in formalin more than 6 hours and less than 48 hours

[page 4 of 4]
MRN: [REDACTED]

Patient: [REDACTED]

Sex/DOB: Female [REDACTED]

Surgical Pathology Report

Collected Date/Time:

Received Date/Time:

Accession Number: [REDACTED]

Time specimen was removed from the patient:

Time specimen was placed in formalin:

Ischemic time: 22 minutes

Dictated by:

Intra Operative Consultation

E. right upper lobe = adenocarcinoma

Special Stains / Slides

20 H&E, 1 FS

Tissue Code

Source: NCI Genomic Data Commons file a080fa18-7be6-49d3-83de-b88b50b3e8fd (TCGA-S2-AA1A.83A6F838-3F30-411F-9982-B8985C7FA52E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).